Somatic mutation profile of tumor specimen TCGA-LB-A8F3-01A (aliquot TCGA-LB-A8F3-01A-11D-A36O-08) from TCGA case TCGA-LB-A8F3, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 64.7 years (23,624 days).
Specimen TCGA-LB-A8F3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e85f31d6-934f-42db-a3b3-c8014e4850cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LB-A8F3-10A (Blood Derived Normal), aliquot TCGA-LB-A8F3-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e607b6d-d7f4-4dd5-b477-2150e900d1e3

The open-access MAF lists 39 somatic variants for this specimen: 32 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 27, Silent 7, Frame Shift Ins 2, Nonsense Mutation 1, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACIN1 | c.3736A>C p.K1246Q | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.346); catalogued as COSV99399772; called by muse, mutect2, varscan2
- ACTBL2 | c.38A>G p.N13S | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.283); catalogued as rs1384054278, COSV70661107; called by muse, mutect2, varscan2
- ACTL9 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 37/266 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs782182119, COSV61006158; called by muse, mutect2, varscan2
- ADGRV1 | c.6235C>T p.L2079F | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as rs529727564, COSV101316091; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMFR | c.1520C>T p.S507L | Missense Mutation (SNP) | VAF 31/1127 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99315992; called by muse, mutect2
- ANAPC2 | c.313C>G p.P105A | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100119112; called by muse, mutect2, varscan2
- ANKRD24 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs373345481; called by muse, mutect2
- BRINP2 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 42/645 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.967); catalogued as COSV100838138; called by muse, mutect2
- CACNA1C | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 80/1228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104404676, COSV59706212; called by muse, mutect2
- CALCA | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100524038; called by muse, mutect2, varscan2
- CBLL2 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 35/484 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as rs868368528, COSV60370252; called by muse, mutect2
- CPE | c.1430A>T p.*477Lext*4 | Nonstop Mutation (SNP) | VAF 41/161 reads (25%) | catalogued as rs1404286621, COSV101291607; called by muse, mutect2, varscan2
- DOCK9 | c.949G>A p.E317K (on ENST00000376460 / NM_001366676.2; = p.E318K on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs1281117985, COSV100239538; called by muse, mutect2
- FAM171B | c.1840C>T p.P614S | Missense Mutation (SNP) | VAF 35/335 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.056); catalogued as rs1481390923, COSV100488683, COSV59008762; called by muse, mutect2, varscan2
- KBTBD6 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 108/418 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs61999308; called by muse, mutect2, varscan2
- KCNA6 | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 14/393 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.735); catalogued as COSV54977957; called by muse, mutect2
- KIF4A | c.2144A>G p.K715R | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV100979545; called by muse, mutect2
- LRRN3 | c.575T>C p.I192T | Missense Mutation (SNP) | VAF 63/380 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100071212; called by muse, mutect2, varscan2
- NLRC5 | c.3006C>G p.C1002W | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); catalogued as COSV99347522; called by muse, mutect2, varscan2
- OGFR | c.1250G>A p.C417Y | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99284201; called by muse, mutect2
- OR8K1 | c.370A>G p.M124V | Missense Mutation (SNP) | VAF 262/1131 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.456); catalogued as COSV99687354; called by muse, mutect2, varscan2
- PCDH19 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 41/402 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV99719987; called by muse, mutect2, varscan2
- PIK3C2B | c.2896C>T p.Q966* | Nonsense Mutation (SNP) | VAF 67/1852 reads (4%) | catalogued as COSV65809043; called by muse, mutect2
- SAMD7 | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV100156963, COSV99045847; called by muse, mutect2, varscan2
- SH3TC1 | c.2795T>A p.L932Q | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99794954; called by muse, mutect2, varscan2
- STAG2 | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 29/430 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV99493786; called by muse, mutect2
- TEAD2 | c.1195A>T p.M399L | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV100115032; called by muse, mutect2
- TMEM104 | c.893C>G p.S298C | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100120748; called by muse, mutect2
- TMEM270 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 57/518 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100260361; called by muse, mutect2, varscan2
- HELB | c.1965dup p.A656Sfs*22 | Frame Shift Ins (INS) | VAF 58/598 reads (10%) | called by mutect2, pindel, varscan2
- HIP1R | c.300+2_300+17del p.X100_splice | Splice Site (DEL) | VAF 36/218 reads (17%) | called by mutect2, pindel
- SP4 | c.761dup p.T255Nfs*6 | Frame Shift Ins (INS) | VAF 46/359 reads (13%) | called by mutect2, pindel, varscan2
- ANKRD27 | c.747T>A p.L249= | Silent (SNP) | VAF 14/466 reads (3%) | catalogued as COSV100042895; called by muse, mutect2
- ATE1 | c.1554C>T p.N518= | Silent (SNP) | VAF 12/206 reads (6%) | catalogued as COSV99817276; called by muse, mutect2
- CCSER2 | c.1377C>T p.A459= | Silent (SNP) | VAF 32/689 reads (5%) | catalogued as COSV99826053; called by muse, mutect2
- LZTS2 | c.1005C>T p.D335= | Silent (SNP) | VAF 12/291 reads (4%) | catalogued as COSV100932201; called by muse, mutect2
- MYO1B | c.2250A>G p.T750= | Silent (SNP) | VAF 21/675 reads (3%) | catalogued as rs1483809792, COSV100269311; called by muse, mutect2
- OR2A7 | c.24C>A p.I8= | Silent (SNP) | VAF 58/533 reads (11%) | catalogued as COSV101512220; called by muse, mutect2, varscan2
- SLC1A4 | c.903T>A p.S301= | Silent (SNP) | VAF 20/548 reads (4%) | catalogued as COSV99309004; called by muse, mutect2
